FM case AD5325 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/5b2ab7d1-2032-4e28-9b48-1249758e1cbd

Male, 65.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the small intestine. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
